Somatic mutation profile of tumor specimen TCGA-OR-A5K5-01A (aliquot TCGA-OR-A5K5-01A-11D-A29I-10) from TCGA case TCGA-OR-A5K5, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 60.0 years (21,907 days).
Specimen TCGA-OR-A5K5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bdde89c-3d42-4a49-b96a-e808c08ffde4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5K5-10A (Blood Derived Normal), aliquot TCGA-OR-A5K5-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5c4a841-3dce-4aba-82c2-5ccfbd51e16b

The open-access MAF lists 130 somatic variants for this specimen: 101 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 28, In Frame Del 7, Nonsense Mutation 3, Frame Shift Del 3, Frame Shift Ins 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 65/196 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ARAP2 | c.3550G>C p.D1184H | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1341874544; called by muse, mutect2, varscan2
- AVPR1A | c.545G>T p.S182I | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54546786; called by muse, mutect2, varscan2
- BZW2 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.288); catalogued as rs1356337797, COSV51754103; called by muse, mutect2, varscan2
- C12orf57 | c.180G>T p.Q60H | Missense Mutation (SNP) | VAF 84/321 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1279269404; called by muse, mutect2, varscan2
- CCDC191 | c.2519_2521del p.K840del | In Frame Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs779707287; called by pindel, varscan2
- CD248 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1278331560; called by muse, mutect2
- CTNND2 | c.2730C>G p.C910W | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100479720, COSV58872802; called by muse, mutect2, varscan2
- EVPL | c.5186C>T p.S1729L | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs766614508, COSV56916347; called by muse, mutect2, varscan2
- HNF4A | c.1156C>A p.H386N | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.254); catalogued as COSV100291673, COSV100291797; called by muse, mutect2, varscan2
- KANSL1 | c.277A>G p.K93E | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs752219095; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRE11 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs757492041; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NABP2 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs371882558; called by muse, mutect2, varscan2
- NTNG1 | c.18C>A p.F6L | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV99638140; called by muse, mutect2, varscan2
- PLXND1 | c.3179A>G p.N1060S | Missense Mutation (SNP) | VAF 76/381 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as rs371911654; called by muse, varscan2
- PRDX1 | c.403_405del p.D135del | In Frame Del (DEL) | VAF 25/93 reads (27%) | catalogued as rs1557613233; called by pindel, varscan2
- SLC28A1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as rs759745634; called by muse, mutect2, varscan2
- SLC2A5 | c.41C>T p.T14M | Missense Mutation (SNP) | VAF 88/224 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs765084352; called by muse, mutect2, varscan2
- SQLE | c.819C>G p.I273M | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.1); catalogued as rs1230378614; called by muse, mutect2, varscan2
- ABCA13 | c.8849G>A p.W2950* | Nonsense Mutation (SNP) | VAF 23/82 reads (28%) | called by muse, mutect2, varscan2
- ABCD4 | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- ADAMTSL4 | c.3113C>T p.P1038L | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ANK3 | c.4729A>T p.M1577L | Missense Mutation (SNP) | VAF 67/318 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD50 | c.2230T>C p.C744R | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ARHGAP15 | c.811A>C p.K271Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- ARL4D | c.502T>C p.C168R | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CCDC142 | c.2114G>C p.S705T (on ENST00000393965 / NM_001365575.2; = p.S698T on NM_032779.4) | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CEMIP2 | c.1472A>G p.N491S | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CNTNAP5 | c.1644C>A p.D548E | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COPB2 | c.2393T>A p.F798Y | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRACD | c.1287G>T p.R429S | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRIM1 | c.1722G>T p.K574N | Missense Mutation (SNP) | VAF 75/264 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP20A1 | c.710A>G p.N237S | Missense Mutation (SNP) | VAF 56/311 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- DACH2 | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 74/299 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DDX18 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 29/147 reads (20%) | called by muse, mutect2, varscan2
- DGKK | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); called by muse, mutect2
- DISP3 | c.1331T>C p.L444P | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK2 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DROSHA | c.818G>T p.R273I | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- DSCAM | c.2986A>G p.I996V | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DST | c.21068C>T p.S7023F (on ENST00000361203 / NM_001374722.1; = p.S4720F on NM_015548.5) | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- DUSP12 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 123/284 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- ENAM | c.3001G>T p.V1001F | Missense Mutation (SNP) | VAF 73/295 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- FMNL2 | c.1636G>A p.G546S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- GABRR2 | c.341C>G p.A114G | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- GAS6 | c.1475A>G p.Y492C | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GLE1 | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 51/298 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.41); called by muse, varscan2
- GLE1 | c.274A>G p.S92G | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, varscan2
- GOLGA4 | c.6577A>C p.T2193P | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GPR82 | c.842G>T p.C281F | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- H3C6 | c.18G>C p.Q6H | Missense Mutation (SNP) | VAF 84/284 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HCFC2 | c.200_211del p.D67_P70del | In Frame Del (DEL) | VAF 20/156 reads (13%) | called by mutect2, pindel
- HEXIM2 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2
- HSPA14 | c.1331_1332del p.Y444* | Frame Shift Del (DEL) | VAF 52/158 reads (33%) | called by mutect2, pindel, varscan2
- HUWE1 | c.6938T>G p.V2313G | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, varscan2
- ISL1 | c.116A>C p.H39P | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITSN2 | c.1334A>G p.E445G | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- JAK3 | c.341A>G p.K114R | Missense Mutation (SNP) | VAF 50/309 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNH1 | c.2188A>C p.I730L (on ENST00000271751 / NM_172362.3; = p.I703L on NM_002238.4) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNH7 | c.2938G>C p.D980H | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- KIF27 | c.1055A>C p.E352A | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LASP1 | c.358-2A>C p.X120_splice | Splice Site (SNP) | VAF 79/343 reads (23%) | called by muse, mutect2, varscan2
- LSM1 | c.292_294del p.E98del | In Frame Del (DEL) | VAF 24/94 reads (26%) | called by pindel, varscan2
- MAGEB6 | c.1015G>C p.D339H | Missense Mutation (SNP) | VAF 76/310 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MCF2L2 | c.610dup p.E204Gfs*50 | Frame Shift Ins (INS) | VAF 33/188 reads (18%) | called by mutect2, pindel, varscan2
- ME2 | c.175_178dup p.T60Rfs*12 | Frame Shift Ins (INS) | VAF 24/104 reads (23%) | called by mutect2, pindel, varscan2
- MTHFD1L | c.1910A>T p.D637V | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MYO15A | c.9214A>G p.T3072A | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.78); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NACC1 | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 46/319 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NTN1 | c.1580G>C p.R527P | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.061); called by muse, varscan2
- OLAH | c.190G>C p.E64Q (on ENST00000378228 / NM_001039702.3; = p.E117Q on NM_018324.3) | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4C11 | c.646T>C p.Y216H | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OTOF | c.5414_5416del p.K1805del (on ENST00000272371 / NM_194248.3; = p.K1038del on NM_004802.4) | In Frame Del (DEL) | VAF 60/293 reads (20%) | called by pindel, varscan2
- PCDHAC1 | c.2725A>G p.I909V | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- PCYT1B | c.729G>C p.Q243H | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- PKHD1 | c.6551G>T p.G2184V | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLEC | c.6139A>T p.K2047* (on ENST00000322810 / NM_201380.4; = p.K1937* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 36/98 reads (37%) | called by muse, mutect2, varscan2
- PRAM1 | c.1961_1963del p.D654del | In Frame Del (DEL) | VAF 30/164 reads (18%) | called by pindel, varscan2
- PTPDC1 | c.974C>T p.S325F (on ENST00000375360 / NM_177995.3; = p.S377F on NM_152422.4) | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTPN7 | c.629C>A p.T210K (on ENST00000495688; = p.T249K on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RAB6A | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- RYK | c.1249A>G p.M417V (on ENST00000620660 / NM_001005861.2; = p.M414V on NM_002958.4) | Missense Mutation (SNP) | VAF 80/153 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- SAT1 | c.416_418del p.F139del | In Frame Del (DEL) | VAF 56/212 reads (26%) | called by mutect2, pindel, varscan2
- SATL1 | c.488G>T p.G163V (on ENST00000395409; = p.G350V on NM_001012980.2) | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SCAF8 | c.884_885del p.V295Efs*38 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | called by pindel, varscan2
- SP4 | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- SPTA1 | c.2347G>C p.A783P | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- SYNCRIP | c.1696A>G p.K566E | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TAF1D | c.158T>G p.V53G | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- THSD7A | c.3062A>G p.H1021R | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMCC1 | c.1683G>C p.K561N (on ENST00000393238 / NM_001349268.2; = p.K237N on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMEM143 | c.195C>G p.D65E | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- TNC | c.5960C>T p.A1987V | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- TRIM11 | c.881A>G p.D294G | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.448); called by muse, mutect2
- TRIP12 | c.4159G>A p.A1387T | Missense Mutation (SNP) | VAF 113/233 reads (48%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- UBR4 | c.8912A>T p.H2971L | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- VWC2L | c.317G>T p.C106F | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WHRN | c.1808G>C p.G603A | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF131 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- ZNF142 | c.3827C>T p.S1276F (on ENST00000411696 / NM_001379660.1; = p.S1076F on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ZNF616 | c.319_320del p.N107* | Frame Shift Del (DEL) | VAF 33/185 reads (18%) | called by mutect2, pindel, varscan2
- AASS | c.364T>C p.L122= | Silent (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- ADRA1B | c.936C>T p.I312= | Silent (SNP) | VAF 27/128 reads (21%) | catalogued as rs1265592542, COSV60700545; called by muse, mutect2, varscan2
- ANGPT1 | c.759G>A p.E253= | Silent (SNP) | VAF 37/191 reads (19%) | called by muse, mutect2, varscan2
- ARID3C | c.147G>T p.G49= | Silent (SNP) | VAF 46/84 reads (55%) | called by muse, mutect2, varscan2
- ATF1 | c.366T>C p.S122= | Silent (SNP) | VAF 66/278 reads (24%) | called by muse, mutect2, varscan2
- CSMD1 | c.8190A>G p.Q2730= (on ENST00000520002; = p.Q2729= on NM_033225.6) | Silent (SNP) | VAF 20/120 reads (17%) | called by muse, mutect2, varscan2
- CSMD3 | c.7872C>A p.V2624= (on ENST00000297405 / NM_001363185.1; = p.V2520= on NM_052900.3) | Silent (SNP) | VAF 28/117 reads (24%) | called by muse, mutect2, varscan2
- DAAM2 | c.2775C>A p.S925= (on ENST00000274867 / NM_001201427.2; = p.S924= on NM_015345.3) | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as rs754385047, COSV51309368; called by muse, mutect2, varscan2
- DCDC1 | c.81A>G p.V27= | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, varscan2
- EHMT2 | c.2113C>T p.L705= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs773169694, COSV64996437; called by muse, mutect2, varscan2
- FRMPD2 | c.1125C>T p.A375= | Silent (SNP) | VAF 45/131 reads (34%) | called by muse, mutect2, varscan2
- IGDCC4 | c.279G>T p.L93= | Silent (SNP) | VAF 54/172 reads (31%) | catalogued as rs757875036; called by muse, mutect2, varscan2
- IRS4 | c.129C>A p.L43= | Silent (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- KLHL7 | c.126G>A p.T42= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as rs150640353; called by muse, mutect2, varscan2
- NAPSA | c.102C>G p.V34= | Silent (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- NMUR1 | c.141G>T p.L47= | Silent (SNP) | VAF 21/196 reads (11%) | called by muse, mutect2, varscan2
- NPAS3 | c.216T>C p.Y72= (on ENST00000356141 / NM_001164749.2; = p.Y42= on NM_022123.3) | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as rs138614075; called by muse, mutect2, varscan2
- NUMBL | c.1116C>T p.A372= | Silent (SNP) | VAF 30/153 reads (20%) | called by muse, mutect2, varscan2
- OSBPL11 | c.1866C>T p.N622= | Silent (SNP) | VAF 9/139 reads (6%) | called by muse, mutect2
- PCDHA7 | c.1809C>T p.Y603= | Silent (SNP) | VAF 130/515 reads (25%) | called by muse, mutect2, varscan2
- PIK3C2G | c.1366C>T p.L456= | Silent (SNP) | VAF 27/125 reads (22%) | called by muse, mutect2, varscan2
- PKD1L1 | c.4422T>C p.H1474= | Silent (SNP) | VAF 26/117 reads (22%) | called by muse, mutect2, varscan2
- PNMA8B | c.1500C>T p.N500= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV66536007; called by muse, mutect2, varscan2
- RORA | c.849G>A p.S283= (on ENST00000335670 / NM_134261.3; = p.S308= on NM_002943.3) | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs199818399; called by muse, mutect2, varscan2
- SLC4A11 | c.594C>T p.I198= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs778740310; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMC1A | c.3024G>A p.Q1008= | Silent (SNP) | VAF 31/106 reads (29%) | called by muse, mutect2, varscan2
- USH2A | c.14592C>A p.L4864= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV56414602; called by muse, mutect2, varscan2
- ZBTB38 | c.1257A>T p.G419= | Silent (SNP) | VAF 44/160 reads (28%) | called by muse, mutect2, varscan2
- EPDR1 | c.-191_-181del | 5'UTR (DEL) | VAF 41/204 reads (20%) | catalogued as rs773406621; called by mutect2, pindel, varscan2
